Surgical pathology report (de-identified scan), TCGA case TCGA-05-4418, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site Indivumed, specimen TCGA-05-4418-01A (Primary Tumor).

/diagnoses:

Locally advanced, peripheral bronchopulmonary, histologically mixed adenocarcinoma of the left lower lobe of the lung with a large-cell and clear-cell, solid and acinar component, mucin formation and localization in S8.

TNM classification on the basis of this material: pT3 pN2 pMX V1 R0, stage IIIA
C 34.1 M 8255/3.

Comment/supplementary remark:

The carcinoma has infiltrated the pericardial fatty tissue. Lymph node metastases can be seen in the hilar region both in the main preparation and in samples 1.) and 4.). The resection margin of the bronchus and vessels as well as the pericardial resection material, the adhered part of the parietal pleura sample 2.) and the lymph nodes of samples 3.) and 5.) are tumor-free.

Source: NCI Genomic Data Commons file 26881ebc-b0e4-444a-8dae-c5e171eb2781 (TCGA-05-4418.4D77E536-98F2-4E34-9E76-ADB4BC79BF5E.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).